Surgical pathology report (de-identified scan), TCGA case TCGA-EO-A1Y5, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University Health Network, specimen TCGA-EO-A1Y5-01A (Primary Tumor).

[page 1 of 4]
LABORATORY MEDICINE PROGRAM

1CD-0-3

carcinoma, serous, NOS 8441/3

Site: Endometrium C54.1

3/4/11 *fw*

Surgical Pathology Consultation Report * Addended *

Patient
Name:
MRN:
DOB:
Gender:
HCN:
Ordering
MD:
Copy To:

Service:
Visit #:
Location:
Facility:

Accession #:
Collected:
Received:
Reported:

Specimen(s) Received

1. Lymph-Node: Pre-Caval Lymph Node
2. Uterus: Uterus, cervix & BSO
3. Omentum
4. Lymph node: RT. Common & external iliac lymph node

Diagnosis

1. Pre-caval lymph nodes
- Metastatic serous carcinoma in one lymph node. (1/1)

2. "Uterus, cervix, bilateral fallopian tubes and ovaries, robotic-assisted total hysterectomy, bilateral salpingo-oophorectomy:

Endometrium:

-SEROUS CARCINOMA.

Myometrium:

- Involved by serous carcinoma to uterine serosa .

Cervix:

- Serous carcinoma, present in lymphatic/vascular spaces

Right & left ovaries:

- Serous carcinoma, present in lymphatic/vascular spaces
- Epithelial inclusion cysts.

Right & left fallopian tubes:

- Serous carcinoma, present in lymphatic/vascular spaces

3. Omentum, partial omentectomy:

- Negative for malignancy.

4. Right common and external iliac lymph nodes:

- Metastatic serous carcinoma in 8 out 17. (8/17)

True Malignancy History		☒
Review Date:	fw 3/6/11	

[page 2 of 4]
Synoptic Data

Specimen:	Uterine corpus Cervix Right ovary Left ovary Right fallopian tube Left fallopian tube Omentum
Procedure:	Simple hysterectomy Bilateral salpingo-oophorectomy Omentectomy
Lymph Node Sampling:	Performed: Pelvic lymph nodes
Specimen Integrity:	Intact hysterectomy specimen
Tumor Site:	Other: both sides
Tumor Size:	Greatest dimension: 2 cm
Histologic Type:	Serous adenocarcinoma
Histologic Grade:	G3: Poorly differentiated
Myometrial Invasion:	Present Depth of invasion: 10 mm Myometrial thickness: 10 mm
Involvement of Cervix:	Not involved
Extent of Involvement of Other Organs:	Right ovary not involved Left ovary not involved Right fallopian tube not involved Left fallopian tube not involved Omentum not involved
Lymph-Vascular Invasion:	Present
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT3a (IIIA): Tumor involves serosa and/or adnexa (direct extension or metastasis)
Regional Lymph Nodes (pN):	pN1 (IIIC2): Regional lymph node metastasis to para-aortic lymph nodes, with or without positive pelvic lymph nodes Pelvic lymph nodes examined: 17 Pelvic lymph nodes involved: 8 Para-aortic lymph nodes examined: 1 Para-aortic lymph nodes involved: 1
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	None identified

by:

Electronically verified

[page 3 of 4]
Clinical History

Endo Ca

Gross Description

1. The specimen container is labeled with the patient's name and as "Lymph Node: Precaval lymph node" consists of a piece of tissue measuring 1.5 x 1.1 x 0.5 cm received fresh. This is examined at intraoperative consultation by frozen section performed on part of the specimen. The specimen is submitted in toto as follows

1A- frozen section block resubmitted.

1B-1D- remainder of the specimen.

2. The specimen container is labeled with the patient's name and as "Uterus: Uterus, cervix and BSO" contains a uterus, cervix, bilateral fallopian tube and bilateral ovaries received in 10% buffered formalin. The uterus measures 8.0 cm SI x 5.7 cm ML x 3.0 cm AP and the cervix measures 2.9 cm. in diameter with a 0.9 cm slit-shaped os. The right and left fallopian tubes measures 7.5 cm in length and 0.7 cm in diameter and 3.5 cm in length and 0.7 cm in diameter respectively. The right and left ovaries measure 2.4 x 1.4 x 0.7 cm and 2.5 x 1.2 x 1.0 cm respectively. The entire specimen weighs 102.8 g. The cut surface of the right and left ovaries are solid in consistency with a yellow-tan to gray-tan appearance otherwise grossly unremarkable. The left fallopian tube grossly appears fimbriated but the right fallopian tube has no identifiable fimbria. The endocervical mucosa and ectocervical mucosa is congested but otherwise grossly unremarkable. There is a polypoid tan-brown endometrial tumor mass noted on the anterior left side cornual area measuring 2.0 x 1.8 x 1.0 cm in depth. The remainder of the endometrium is flattened, lush and slightly nodular. The uterine serosa is congested, with fibrous adhesions and an area on the posterior serosa which is nodular measuring 1.8 x 1.0 cm. Representative sections are submitted as follows:

2A-2B- remainder of right ovary submitted in toto.

2C-2D- remainder of right fallopian tube submitted in toto.

2E-2F-remainder of left ovary submitted in toto.

2G-2H-remainder of left fallopian tube and query left fimbria submitted in toto.

2I-2K-full transverse sections of anterior endomyometrium with tumor

2L-2M-longitudinal section of the anterior lower uterine segment

2N-2O- anterior cervix

2P-2R-full transverse sections of the posterior endomyometrium

2S-2U-transverse sections of the posterior left myometrium with serosal nodularity

2V-2W-longitudinal section of the posterior lower uterine segment

2X-2Y-posterior cervix

One piece left fallopian tube, left ovary, right fallopian tube, right ovary, and one piece endometrial CA are stored frozen.

3. The specimen container is labeled with the patient's name and as "omentum" contains a single piece of an unoriented fibroadipose tissue received in 10% buffered formalin. The tissue measures 10.5 x 7.5 x 0.7 cm and weighs 24.7 g.

On serial sectioning, the cut surface is predominantly fatty with no nodules identified grossly.

Representative sections are submitted as follows:

3A-3E-representative sections submitted

4. The specimen container is labeled with the patient's name and as "Lymph Node: Right common and external iliac lymph node" consists of multiple fragments of unoriented fatty tissue measuring in aggregate 6.5 x 3.0 x 1.3 cm received in 10% buffered formalin. Within the fatty tissue, multiple lymph nodes are identified ranging in size from 0.5 cm to 1.7 cm. The specimen is submitted in toto as follows:

4A- one lymph node bisected

4B- one lymph node bisected

4C-multiple lymph nodes

4D- multiple lymph nodes

4E-one lymph node bisected

4F-4H-remainder of fatty tissue.

[page 4 of 4]
Quick Section Diagnosis

1. Pre-caval lymph node: Positive for high-grade adenocarcinoma.

Called at :

Addendum

MD

Status: Signed Out

Date Reported:

Addendum Diagnosis

Tumor cells are show diffuse and strong positivity for P53, p16 and focal positivity for ER. They are negative for WT-1 and PR. MMR repair gene assessment for MSH-6, PMS-2, MLH-1 and MLH-2 show intact genes.

Source: NCI Genomic Data Commons file f8ef9850-e847-4fee-806f-9cd5d75df98f (TCGA-EO-A1Y5.B3A96371-1CD6-4B08-BDA5-C8CD7C7DE81F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).